Somatic mutation profile of cancer-model specimen HCM-BROD-0871-C49-85M (Adherent Cell Line, passage 18; aliquot HCM-BROD-0871-C49-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0871-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.7 years (22,167 days).
Specimen HCM-BROD-0871-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 18.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fa251e6-1562-49aa-8490-cda6f2d73715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0871-C49-11A (Solid Tissue Normal), aliquot HCM-BROD-0871-C49-11A-11D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0b9e9cc-6b30-49e1-80ec-27d82652ba11

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Splice Site 4, Frame Shift Del 3, 3'UTR 3, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 195/197 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.033); catalogued as rs1445271917; called by muse, mutect2, varscan2
- ATP6V1B1 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs200839517, COSV52269890, COSV99314546; called by muse, mutect2, varscan2
- CALCR | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs146344939, COSV100810525; called by muse, mutect2, varscan2
- CHMP7 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.29); catalogued as rs973607314; called by muse, mutect2
- FGF14 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1228022005, COSV65953827; called by muse, mutect2, varscan2
- GLRB | c.1368C>G p.N456K | Missense Mutation (SNP) | VAF 225/441 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0.098); catalogued as rs747170836; called by muse, mutect2, varscan2
- INHBB | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 233/506 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1303161649; called by muse, mutect2, varscan2
- ITGA6 | c.1945G>C p.D649H (on ENST00000442250; = p.D610H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/293 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99904994; called by muse, varscan2
- KLRG2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765088717, COSV100572614; called by muse, mutect2, varscan2
- MYH2 | c.5624A>G p.D1875G | Missense Mutation (SNP) | VAF 115/223 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1364758773; called by muse, mutect2, varscan2
- MYO9A | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs148826761; called by muse, mutect2, varscan2
- NEURL4 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs190339983; called by muse, mutect2, varscan2
- NPHP1 | c.1646T>A p.L549H (on ENST00000393272 / NM_207181.4; = p.L550H on NM_000272.5) | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57210359; called by muse, mutect2, varscan2
- PPFIA3 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 75/551 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99418305; called by muse, mutect2, varscan2
- RAPSN | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 212/404 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs148600999; called by muse, mutect2, varscan2
- SCAND1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 170/390 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs776778597; called by muse, mutect2, varscan2
- SDR16C5 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 132/296 reads (45%) | catalogued as COSV58125353; called by muse, mutect2, varscan2
- SLC6A3 | c.1398+1G>T p.X466_splice | Splice Site (SNP) | VAF 113/766 reads (15%) | catalogued as COSV54363493; called by muse, mutect2, varscan2
- SPEN | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 182/338 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs138355680; called by muse, mutect2, varscan2
- ABCA1 | c.3188T>G p.V1063G | Missense Mutation (SNP) | VAF 185/346 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS13 | c.3716-1G>C p.X1239_splice | Splice Site (SNP) | VAF 128/261 reads (49%) | called by muse, mutect2, varscan2
- ADGRL2 | c.1326dup p.G443Rfs*28 | Frame Shift Ins (INS) | VAF 42/424 reads (10%) | called by mutect2, pindel
- ALDH1A2 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARFGAP2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 223/430 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARHGEF39 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 160/317 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CENPJ | c.764del p.T255Ifs*25 | Frame Shift Del (DEL) | VAF 127/358 reads (35%) | called by mutect2, pindel, varscan2
- DNAH3 | c.11813T>C p.L3938P | Missense Mutation (SNP) | VAF 140/460 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSG2 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- FYB2 | c.1800A>C p.E600D | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- HBG1 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 237/264 reads (90%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IL15 | c.361A>T p.S121C | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LIN54 | c.1213_1214del p.P405Nfs*25 | Frame Shift Del (DEL) | VAF 140/371 reads (38%) | called by mutect2, pindel, varscan2
- MEIOC | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 167/372 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MSH3 | c.293A>T p.K98I | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- MYO7B | c.6272T>C p.L2091P | Missense Mutation (SNP) | VAF 166/577 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NRG1 | c.1700G>T p.S567I (on ENST00000405005 / NM_013964.5; = p.S572I on NM_013956.5) | Missense Mutation (SNP) | VAF 221/461 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- P2RY13 | c.48+1G>A p.X16_splice | Splice Site (SNP) | VAF 87/198 reads (44%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POFUT2 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 141/334 reads (42%) | called by muse, mutect2, varscan2
- PRR29 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 178/360 reads (49%) | called by muse, varscan2
- RFX4 | c.715A>T p.M239L (on ENST00000392842 / NM_213594.3; = p.M145L on NM_032491.6) | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- RNF113A | c.823A>T p.T275S | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNPEPL1 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 158/333 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SEC13 | c.98C>T p.S33L (on ENST00000350697 / NM_183352.3; = p.S36L on NM_030673.4) | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SHOX | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 68/570 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVEP1 | c.4952G>T p.G1651V | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.1158del p.D387Tfs*19 (on ENST00000256246; = p.D770Tfs*19 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 81/282 reads (29%) | called by mutect2, pindel, varscan2
- THSD1 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 27/572 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2
- TMEM30B | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 353/355 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TNRC18 | c.5583G>T p.E1861D | Missense Mutation (SNP) | VAF 144/998 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPMT | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- VWA3B | c.3158-1G>T p.X1053_splice | Splice Site (SNP) | VAF 142/288 reads (49%) | called by muse, mutect2, varscan2
- ZNF668 | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 321/695 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCN3 | c.117C>T p.C39= | Silent (SNP) | VAF 257/587 reads (44%) | catalogued as rs764279785, COSV52383385; called by muse, mutect2, varscan2
- FOXD3 | c.1053C>G p.A351= | Silent (SNP) | VAF 199/478 reads (42%) | called by muse, mutect2, varscan2
- NLRP3 | c.2709C>T p.S903= | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as rs145787821; called by muse, mutect2, varscan2
- NTF4 | c.72C>G p.S24= | Silent (SNP) | VAF 170/331 reads (51%) | called by muse, mutect2, varscan2
- OR5P3 | c.51A>G p.L17= | Silent (SNP) | VAF 120/326 reads (37%) | called by muse, mutect2
- PREX2 | c.999A>T p.T333= | Silent (SNP) | VAF 32/253 reads (13%) | called by muse, mutect2, varscan2
- PSD3 | c.282C>A p.V94= | Silent (SNP) | VAF 204/400 reads (51%) | called by mutect2, varscan2
- SLC18A1 | c.1281G>C p.G427= | Silent (SNP) | VAF 199/445 reads (45%) | catalogued as rs536694184; called by muse, mutect2, varscan2
- SYTL1 | c.78T>C p.P26= | Silent (SNP) | VAF 260/473 reads (55%) | called by muse, mutect2, varscan2
- WDR19 | c.1044C>G p.T348= | Silent (SNP) | VAF 142/347 reads (41%) | catalogued as COSV99975025; called by muse, mutect2, varscan2
- ZNF215 | c.696A>G p.P232= | Silent (SNP) | VAF 63/75 reads (84%) | called by muse, mutect2, varscan2
- ZNF708 | c.297A>C p.I99= | Silent (SNP) | VAF 134/297 reads (45%) | called by muse, mutect2, varscan2
- ATXN2L | c.*133C>T | 3'UTR (SNP) | VAF 250/570 reads (44%) | catalogued as rs1347842613, COSV100295070, COSV57380381; called by muse, mutect2, varscan2
- KLC2 | c.*343C>G | 3'UTR (SNP) | VAF 234/475 reads (49%) | catalogued as rs1182338298; called by muse, mutect2, varscan2
- MFSD4B | c.*47G>C | 3'UTR (SNP) | VAF 52/470 reads (11%) | called by muse, mutect2, varscan2
- TPK1 | c.185+15091C>T | Intron (SNP) | VAF 156/320 reads (49%) | called by muse, mutect2, varscan2
- TPM4 | chr19:16076627 C>T | 5'Flank (SNP) | VAF 66/570 reads (12%) | called by muse, mutect2, varscan2
